TARGET case TARGET-10-PASLCJ — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2e365aa6-ede7-4b5d-8937-85d694cd3fdc

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 1 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 1.0 years (383 days); Year of diagnosis: 2009; Days to last follow up: 2,303 days (6.3 years).
   Treatment given: Protocol identifier: AALL0331.

Follow-up (2 entries)
- Days to follow up: 1,220 days (3.3 years); Days to first event: 1,220 days (3.3 years); First event: Relapse.
- Days to follow up: 2,303 days (6.3 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow; Year of follow up: 2015.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 12.3 ×10³/µL.
- Day 8: Bone Marrow blast count 0%; Minimal Residual Disease (Flow Cytometry) 0.04%.
- Day 29: Bone Marrow blast count 0%; Minimal Residual Disease (Flow Cytometry) 0%.

Biospecimens (3 samples)
- Samples TARGET-10-PASLCJ-03A, TARGET-10-PASLCJ-03B (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-10-PASLCJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Dicentric_20230727.xlsx (sheet Clinical Data):
- First Event: Relapse (off-therapy)
- Overall Survival Time in Days: 2303
- WBC at Diagnosis: 12.3
- CNS Status at Diagnosis: CNS 2
- MRD Day 8: 0.04
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 0
- MRD Day 29 Sensitivity: 0.01
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 0
- BMA Blasts Day 29: 0
- Karyotype: 45,XX,dic(9;20)(p13;q11.2)[12]/45,idem,der(19)t(9;19)(p13;p13.3)[8]
- DNA Index: 1.0808
- Alternate Therapy: Chemotherapy
- Cell of Origin: B-Precursor
